Somatic mutation profile of tumor specimen TCGA-TT-A6YJ-01A (aliquot TCGA-TT-A6YJ-01A-11D-A35I-08) from TCGA case TCGA-TT-A6YJ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 45.1 years (16,475 days).
Specimen TCGA-TT-A6YJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8253568b-e9c8-4301-bbda-3eaf64f72f60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TT-A6YJ-10B (Blood Derived Normal), aliquot TCGA-TT-A6YJ-10B-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13d07964-18f7-438e-a84d-5661c80fa616

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL34 | c.77T>C p.M26T | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1410404488; called by muse, mutect2, varscan2
- IQSEC3 | c.1375G>A p.A459T (on ENST00000538872 / NM_001170738.2; = p.A156T on NM_015232.1) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs1249537354, COSV58285935; called by muse, mutect2
- KCNH5 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.103); catalogued as COSV100525215; called by muse, mutect2
- SYT6 | c.860G>A p.R287H (on ENST00000610222 / NM_001366225.1; = p.R202H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373704316; called by muse, mutect2, varscan2
- DLAT | c.1576_1580del p.V526* | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- IGKV3-20 | c.40T>C p.W14R | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- NF1 | c.1722-20_1751del p.X574_splice | Splice Site (DEL) | VAF 21/31 reads (68%) | called by mutect2, pindel
- TAF1L | c.2484T>A p.V828= | Silent (SNP) | VAF 47/107 reads (44%) | called by muse, mutect2, varscan2
